Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A1NU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A1NU-01A (Primary Tumor).

[page 1 of 5]
1CD-0-3

Adenocarcinoma, serous, NOS 8441/3
Site: Endometrium c54.1 2/24/11
for

- Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

A. Abdomen, panniculectomy: Skin and subcutaneous tissue, 1880.0 grams, identified grossly.

B. Uterus, bilateral ovaries and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: High-grade serous adenocarcinoma is identified forming a polypoid mass (4.7 x 2.4 x 0.8 cm) located in the fundus and left posterior uterine wall. The tumor invades 0.3 cm into the myometrium (total wall thickness 1.9 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. Endometriosis is identified in the cul-de-sac. A single submucosal leiomyoma (3.6 x 3.0 x 2.7 cm) is identified underlying the endometrial tumor. The bilateral ovaries and fallopian tubes are not involved.

C. Lymph nodes, left pelvic, lymphadenectomy: Multiple (13) left pelvic lymph nodes are negative for tumor.

D. Lymph nodes, right pelvic, lymphadenectomy: Multiple (24) right pelvic lymph nodes are negative for tumor.

E. Lymph nodes, left para-aortic, biopsy: Multiple (3) left para-aortic lymph nodes are negative for tumor.

F. Gonadal vessel, left, excision: Negative for tumor.

[page 2 of 5]
G. Lymph nodes, right para-aortic, biopsy: Multiple (5) right para-aortic lymph nodes are negative for tumor.

H. Gonadal vessel, right, excision: Negative for tumor.

I. Omentum, omentectomy: Accessory spleen (0.5 cm in greatest dimension) without diagnostic abnormality.

J-T: Peritoneum, cul-de-sac, right colic gutter, left colic gutter, right pelvic sidewall, left pelvic sidewall, small bowel serosa, small bowel mesentery, large bowel serosa, large bowel mesentery, right diaphragm, bladder peritoneum, staging biopsies: Negative for tumor, all specimens.

With available surgical material [AJCC pT1aN0] (7th edition, 2010).

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "pannus" is an 1880.0 gram portion of skin and subcutaneous tissue. There is a 7.0 x 5.3 x 3.2 cm portion of circumscribed fat in the central portion of the specimen.
Gross

[page 3 of 5]
only.

B. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 130.0 gram uterus with attached bilateral fallopian tubes and ovaries. The anterior uterine serosa and cul-de-sac have focal adhesions suspicious for endometriosis. There is a 4.7 x 2.4 x 0.8 cm polypoid mass in the fundus and left posterior wall of the endometrial cavity with an underlying 3.6 x 3.0 x 2.7 cm submucosal leiomyoma. Grossly, the tumor invades 0.3 cm into a 1.9 cm thick myometrium. There is a 1.6 x 0.8 x 0.8 cm right ovary with a smooth outer surface and a solid cut surface with a 6.8 x 0.6 cm right fallopian tube which is unremarkable. There is a 1.0 x 0.5 x 0.4 cm left ovary with a ragged outer surface and a solid cut surface with a 7.7 x 0.6 cm left fallopian tube which is unremarkable. Representative sections are submitted.

C. Received fresh labeled "left pelvic lymph nodes" is a 5.5 x 5.4 x 1.4 cm aggregate of adipose and lymphatic tissue. Multiple (12) lymph nodes are identified. All lymph nodes submitted.

D. Received fresh labeled "right pelvic lymph nodes" is a 7.7 x 4.7 x 1.8 cm aggregate of adipose and lymphatic tissue. Multiple (23) lymph nodes are identified. All lymph nodes submitted.

E. Received fresh labeled "left para-aortic lymph nodes" is a 4.2 x 1.3 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymph nodes submitted.

F. Received fresh labeled "left gonadal vessels" is a 4.1 cm in

[page 4 of 5]
length by 0.3 cm in diameter portion of unremarkable blood vessel. A representative section is submitted.

G. Received fresh labeled "right para-aortic lymph nodes" is a 3.6 x 2.8 x 1.1 cm aggregate of adipose and lymphatic tissue. All lymph nodes submitted.

H. Received fresh labeled "right gonadal vessels" is a 4.0 cm in length by 0.4 cm in diameter portion of unremarkable blood vessel. A representative section is submitted.

I. Received fresh labeled "omentum" is a 24.0 x 3.2 x 2.1 cm portion of omentum. No masses are identified grossly. A 0.5 cm in greatest dimension accessory spleen is identified. A representative section is submitted.

J. Received fresh labeled "cul-de-sac" is a 1.0 x 0.6 x 0.4 cm aggregate of pink-tan tissue, which is entirely submitted.

K. Received fresh labeled "right colic gutter" is a 2.0 x 1.3 x 0.6 cm aggregate of pink-tan tissue, which is entirely submitted.

L. Received fresh labeled "left colic gutter" is a 1.6 x 0.6 x 0.4 cm aggregate of pink-tan tissue, which is entirely submitted.

M. Received fresh labeled "right pelvic sidewall" is a 1.8 x 1.4 x 1.0 cm aggregate of pink-tan tissue, which is entirely submitted.

N. Received fresh labeled "left pelvic sidewall" is a 1.5 x 0.4 x

[page 5 of 5]
0.3 cm aggregate of pink-tan tissue, which is entirely submitted.

O. Received fresh labeled "small bowel serosa" is a 0.6 x 0.3 x 0.3 cm aggregate of pink-tan tissue, which is entirely submitted.

P. Received fresh labeled "small bowel mesentery" is a 0.7 x 0.6 x 0.4 cm aggregate of pink-tan tissue, which is entirely submitted.

Q. Received fresh labeled "large bowel serosa" is a 0.6 x 0.4 x 0.4 cm aggregate of pink-tan tissue, which is entirely submitted.

R. Received fresh labeled "large bowel mesentery" is a 2.5 x 1.4 x 1.2 cm aggregate of pink-tan tissue, which is entirely submitted.

S. Received fresh labeled "right diaphragm" is an 0.5 x 0.3 x 0.3 cm aggregate of pink-tan tissue, which is entirely submitted.

T. Received fresh labeled "bladder peritoneum" is an 0.7 x 0.6 x 0.4 cm aggregate of pink-tan tissue, which is entirely submitted.

Source: NCI Genomic Data Commons file e31ba6f0-51e9-4c2a-b223-2134766aef9d (TCGA-D1-A1NU.08AE92E6-EDAB-4059-AF51-4A8522EDD463.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).